Surgical pathology report (de-identified scan), TCGA case TCGA-D7-8573, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-8573-01A (Primary Tumor).

Material:

1) Material: stomach, Method of collection: Lesion resection.

Histopathological diagnosis:

Examination performed on:

(including test No. G-3155/12):

Adenocarcinoma tubuläre ventriculi. G3, pT3, pNO. Tubular adenocarcinoma of the stomach

Typus intestinalis sec Lauren. Intestinal type Lauren

Macroscopic description:

Adenocarcinoma tubuläre G3.

Cancerous proliferation reaches the peritoneal surface of the stomach. Surgical incision lines free of neoplastic lesions.

Mucosa outside the tumour showing features of chronic inflammation with focal intestinal metaplasia.

Adjacent part of the omentum free of cancerous lesions.

3 - (lesser curvature): Lymphonodulitis reactiva No VIII.

4 - (greater curvature) :Lymphonodulitis reactiva No VII.

5 - (peripyloric):Lymphonodulitis reactiva No IV.

Microscopic description:

The specimen containing the stomach, after being incised along the greater curvature sized 18.5 x 16cm with the omentum sized 30 x 16cm. Cauliflower-shaped tumour on the greater curvature sized 5.5 x 4.5 x 2.4 cm. Distance from the proximal end: 8.0cm, from distal end: 5.0cm.

Assistant:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file df4cb911-15de-4617-89bd-1ef4ff1fcd13 (TCGA-D7-8573.B7306A47-697D-4ED3-BBE1-81D49674A8F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).